MMRF case MMRF_1354 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e6cbbc04-f3dc-496c-84eb-1f348e2196e0

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.4 years (27,527 days); ISS stage: III; Days to last known disease status: 1,427 days (3.9 years); Days to last follow up: 1,427 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 67 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 389 days (1.1 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 391 days (1.1 years); Days to treatment end: 1,175 days (3.2 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,089 days (3.0 years).
   Treatment given: Therapeutic agents: Lenalidomide + Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,175 days (3.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 3.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 155 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.468 mg/dL; Immunoglobulin G 4.1 g/L; Immunoglobulin A 35.3 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 5.66 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 9.5 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 0.22 mg/dL.
- Day 103 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.83 mmol/L.
- Day 209 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 7.7 mmol/L.
- Day 293 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 2.02 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.
- Day 391 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 8.97 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 467 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 6.27 mmol/L.
- Day 545 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.766 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 8.36 mmol/L.
- Day 656 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.909 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.72 mmol/L.
- Day 726 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 845 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 5.23 mmol/L.
- Day 895 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 5.39 mmol/L.
- Day 1,021 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.895 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 6.05 mmol/L.
- Day 1,147 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 5.5 g/dL; Glucose 6.71 mmol/L.
- Day 1,175 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.74 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 6.16 mmol/L.
- Day 1,266 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 5.41 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 5 g/dL; Glucose 6.11 mmol/L.
- Day 1,363 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.923 mg/dL; Immunoglobulin G 5.19 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 6.44 mmol/L.
- Day 1,427 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.4 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day 0: Weight: 66 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_1354_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1354_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1354_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 209 days.
